Somatic mutation profile of tumor specimen ALCH-AE4T-TTP1-A (aliquot ALCH-AE4T-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AE4T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.5 years (20,986 days).
Specimen ALCH-AE4T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b94866a2-1b18-4844-aeb4-c7513ec3ed03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE4T-NB1-A (Blood Derived Normal), aliquot ALCH-AE4T-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e890127-b2a5-4036-a288-0876b4826edc

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Intron 1, Splice Site 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMT2 | c.1182C>G p.F394L | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as COSV51781314; called by muse, mutect2
- PLEKHH1 | c.2264G>A p.R755K | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1316471610; called by muse, mutect2, varscan2
- SEMA5B | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs866732282; called by muse, mutect2
- SGCE | c.733G>A p.G245S (on ENST00000647096; = p.G209S on NM_003919.3) | Missense Mutation (SNP) | VAF 19/420 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56018002; called by muse, mutect2
- SLC5A5 | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 32/643 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1191784651, COSV99715205; called by muse, mutect2
- STRADA | c.512C>T p.A171V (on ENST00000336174 / NM_001363786.1; = p.A134V on NM_153335.6) | Missense Mutation (SNP) | VAF 19/628 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.105); catalogued as rs1004131748, COSV55564177; called by muse, mutect2
- UBE2G2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 24/608 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs782374048, COSV58367517; called by muse, mutect2
- ACAN | c.6450C>A p.S2150R | Missense Mutation (SNP) | VAF 35/586 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); called by muse, mutect2
- ARHGAP6 | c.2561T>A p.L854Q (on ENST00000337414 / NM_013427.3; = p.L651Q on NM_013423.3) | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.025); called by muse, mutect2
- CDC23 | c.995A>T p.E332V | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH7 | c.890T>C p.M297T | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- CILP2 | c.2349C>A p.S783R | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HS3ST4 | c.602T>G p.L201R | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- IGHMBP2 | c.1236-2A>C p.X412_splice | Splice Site (SNP) | VAF 18/339 reads (5%) | called by muse, mutect2
- KRT31 | c.753C>G p.T251= | Splice Region (SNP) | VAF 13/308 reads (4%) | called by muse, mutect2
- LCOR | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 44/1004 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2
- MAP3K8 | c.1093A>T p.I365L | Missense Mutation (SNP) | VAF 31/872 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRMT5 | c.1327C>G p.L443V | Missense Mutation (SNP) | VAF 18/638 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.258); called by muse, mutect2
- TRPM6 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 54/733 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF541 | c.2007G>T p.R669S | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.023); called by muse, mutect2
- H1-1 | c.63C>G p.G21= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- LSAMP | c.414C>T p.S138= | Silent (SNP) | VAF 26/521 reads (5%) | called by muse, mutect2
- PADI2 | c.1581C>T p.T527= | Silent (SNP) | VAF 18/329 reads (5%) | called by muse, mutect2
- PASD1 | c.2049G>A p.L683= | Silent (SNP) | VAF 30/528 reads (6%) | catalogued as rs1417173842; called by muse, mutect2
- SLC7A11 | c.585C>A p.T195= | Silent (SNP) | VAF 17/307 reads (6%) | catalogued as rs1172130468; called by muse, mutect2
- UBR3 | c.819A>G p.Q273= | Silent (SNP) | VAF 15/267 reads (6%) | catalogued as rs1467557834; called by muse, mutect2
- CEROX1 | n.2880G>A | RNA (SNP) | VAF 80/681 reads (12%) | catalogued as rs375744448; called by muse, mutect2, varscan2
- DISC1 | c.1634+3618C>A | Intron (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2, varscan2
